Somatic mutation profile of tumor specimen TCGA-BC-A5W4-01A (aliquot TCGA-BC-A5W4-01A-11D-A28X-10) from TCGA case TCGA-BC-A5W4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,503 days).
Specimen TCGA-BC-A5W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e3464f7-e985-448d-bd85-b9f8941aa447.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A5W4-10A (Blood Derived Normal), aliquot TCGA-BC-A5W4-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21f92ee1-8ba1-40e1-bada-5854c78517c0

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Splice Region 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTR8 | c.443T>G p.L148* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs1052615721, COSV51635213; called by muse, varscan2
- ANKRD12 | c.2677_2679del p.A893del | In Frame Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs766855546; called by pindel, varscan2
- ANO10 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1183784960, COSV52728770, COSV52730285; called by muse, mutect2, varscan2
- ARL9 | c.709A>G p.T237A (on ENST00000640821 / NM_001363794.2; = p.T95A on NM_206919.2) | Missense Mutation (SNP) | VAF 74/83 reads (89%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV63991050; called by muse, mutect2, varscan2
- ARMC9 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV63019549; called by muse, mutect2, varscan2
- B4GALNT4 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs144647644; called by muse, mutect2, varscan2
- BMP2 | c.608G>T p.R203M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV66577090; called by muse, mutect2, varscan2
- CACNA1C | c.477G>T p.L159= | Splice Region (SNP) | VAF 70/83 reads (84%) | catalogued as rs1243683248, COSV59699117; called by mutect2, varscan2
- CCDC71 | c.859C>G p.R287G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV58909711, COSV58909842; called by muse, mutect2, varscan2
- CHD6 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64688578; called by muse, mutect2, varscan2
- COL11A1 | c.1572+2T>A p.X524_splice | Splice Site (SNP) | VAF 60/135 reads (44%) | catalogued as COSV62174145; called by muse, mutect2, varscan2
- CTNNB1 | c.1103T>A p.L368H | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV62690954; called by muse, mutect2, varscan2
- DCLK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1340568626, COSV55173920; called by muse, mutect2, varscan2
- EMC7 | c.222C>G p.H74Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV56626613; called by muse, mutect2, varscan2
- EPB41L3 | c.936G>C p.M312I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59445647; called by muse, mutect2, varscan2
- EXOC6 | c.1814T>C p.L605P | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99592493; called by muse, varscan2
- FAT2 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55814272; called by muse, varscan2
- FLNB | c.2990C>G p.T997R | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.094); catalogued as COSV55871585; called by muse, mutect2, varscan2
- FLT4 | c.2019G>A p.Q673= | Splice Region (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56099728; called by muse, mutect2, varscan2
- FYN | c.1605A>C p.E535D | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57610186; called by muse, mutect2, varscan2
- GLI3 | c.4319C>A p.S1440Y | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV67885620; called by muse, mutect2, varscan2
- HDAC9 | c.2381T>A p.F794Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as COSV67767816; called by muse, mutect2, varscan2
- ITGB6 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791118; called by muse, mutect2, varscan2
- LCMT2 | c.645C>G p.F215L | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV59789613; called by muse, mutect2, varscan2
- MBD3L2 | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs1189494293; called by mutect2, varscan2
- MYOF | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs553662967, COSV63700705; called by muse, mutect2, varscan2
- NRROS | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs368543951; called by muse, mutect2, varscan2
- NUP133 | c.3122G>A p.R1041K | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1210618351, COSV54568570; called by muse, mutect2, varscan2
- OMG | c.1033T>A p.S345T | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55987724; called by muse, mutect2, varscan2
- PCLO | c.4402A>G p.I1468V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61617843; called by muse, mutect2, varscan2
- PLCB4 | c.1043A>G p.Q348R | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53793467, COSV53794238; called by muse, varscan2
- PRCP | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57287658; called by muse, mutect2, varscan2
- PRICKLE1 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58204392; called by muse, mutect2, varscan2
- PTK2B | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 92/219 reads (42%) | catalogued as COSV57750581; called by muse, mutect2, varscan2
- SIGLEC14 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 179/403 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as COSV55777731, COSV99707845; called by muse, mutect2, varscan2
- SIPA1L3 | c.3464G>C p.R1155P | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55909376; called by muse, varscan2
- SKAP2 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1369467943, COSV61721655; called by muse, mutect2, varscan2
- SPAG17 | c.5279C>T p.P1760L | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60453574; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.839G>A p.C280Y | Missense Mutation (SNP) | VAF 66/132 reads (50%) | PolyPhen probably damaging (1); catalogued as rs759824508, COSV59562278; called by muse, mutect2, varscan2
- SVEP1 | c.6152A>G p.Y2051C | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836173; called by muse, mutect2, varscan2
- TEK | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV66227630; called by muse, mutect2, varscan2
- THADA | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 211/294 reads (72%) | catalogued as rs1174263513, COSV57676761; called by muse, mutect2, varscan2
- THEMIS | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV64069407; called by muse, mutect2, varscan2
- TICAM1 | c.1022C>A p.T341N | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1401418673, COSV50229671; called by muse, mutect2, varscan2
- TRPM1 | c.4119A>T p.K1373N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV56630990; called by muse, mutect2, varscan2
- TTC16 | c.2473G>C p.G825R | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV60159964; called by muse, mutect2
- TTN | c.39343C>A p.H13115N (on ENST00000591111; = p.H5691N on NM_003319.4) | Missense Mutation (SNP) | VAF 49/98 reads (50%) | PolyPhen benign (0.318); catalogued as COSV59905634; called by muse, mutect2, varscan2
- UBN1 | c.2291C>A p.S764Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs764055535, COSV52166056; called by muse, mutect2, varscan2
- VCAN | c.6625A>C p.T2209P | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54097869; called by muse, mutect2, varscan2
- ZDHHC5 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs772341043, COSV54705204; called by muse, mutect2, varscan2
- ZNF687 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs762937626, COSV60678048; called by muse, mutect2, varscan2
- ZNF710 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs753434936, COSV51561794; called by muse, mutect2, varscan2
- HSP90AB1 | c.1446del p.I483Sfs*31 | Frame Shift Del (DEL) | VAF 25/49 reads (51%) | called by mutect2, pindel, varscan2
- IGHV3-73 | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KDM3A | c.59del p.L20Rfs*42 | Frame Shift Del (DEL) | VAF 49/95 reads (52%) | called by mutect2, pindel, varscan2
- NUMA1 | c.6124-6_6127del p.X2042_splice | Splice Site (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- BPGM | c.321T>C p.H107= | Silent (SNP) | VAF 111/270 reads (41%) | catalogued as rs1007481067, COSV61323987; called by muse, mutect2, varscan2
- CCDC74B | c.603C>A p.P201= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as COSV60101027; called by muse, mutect2, varscan2
- CELSR2 | c.7716G>A p.L2572= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as COSV54767425; called by muse, mutect2, varscan2
- EPHA6 | c.1944C>T p.A648= (on ENST00000389672 / NM_001080448.3; = p.A40= on NM_173655.4) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs372907476; called by muse, mutect2, varscan2
- KCNN1 | c.1080C>T p.L360= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs377483438; called by muse, mutect2, varscan2
- KIR3DL2 | c.1248G>A p.Q416= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as COSV54389602; called by muse, mutect2, varscan2
- NLRP11 | c.390C>T p.Y130= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as rs1366344449, COSV64085840; called by muse, mutect2, varscan2
- PDZRN3 | c.1866C>T p.N622= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs553747931, COSV55190281; called by muse, mutect2, varscan2
- PIN4 | c.34C>A p.R12= | Silent (SNP) | VAF 162/168 reads (96%) | catalogued as COSV54484607; called by muse, mutect2
- SNX13 | c.1029A>G p.V343= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV68063953; called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.990C>A p.T330= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs1321903867, COSV56571714; called by muse, mutect2, varscan2
- WDR1 | c.1743C>T p.S581= (on ENST00000382452; = p.S441= on NM_005112.5) | Silent (SNP) | VAF 64/185 reads (35%) | catalogued as COSV66723389; called by muse, mutect2, varscan2
- ZDHHC12 | c.444G>A p.L148= | Silent (SNP) | VAF 38/245 reads (16%) | catalogued as rs752723276, COSV52575028; called by muse, varscan2
- BAX | c.474+124C>T | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as rs774285236, COSV53169178; called by muse, mutect2, varscan2
